Gene-level copy-number profile of tumor specimen TCGA-B6-A0IO-01A from TCGA case TCGA-B6-A0IO, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.6 years (24,322 days).
Specimen TCGA-B6-A0IO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e9f6dacc-c812-45f5-8ec1-d70866537325.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0IO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4ca61c7f-7934-4da6-860e-a5168a148326

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 224; copy number 2: 8,875; copy number 3: 15,498; copy number 4: 22,212; copy number 5: 8,470; copy number 6: 3,889; copy number 7: 215; copy number 8: 136; copy number 9: 109; copy number 10: 60; copy number 12: 39; copy number 15: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0IO-01A-11D-A036-01): tumor purity 0.67, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:129,094,749–129,114,028, 2 genes: ISOC1, MIR4633.
- chr9:21,802,636–29,826,711, 77 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 210 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:104,126,341–105,876,604, 27 genes, copy number 9–15: ORC5, LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P, AC007384.1, LINC01004, KMT2E-AS1, KMT2E, AC005070.3, SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1.
- chr15:87,325,829–88,656,483, 19 genes, copy number 9: AC020687.1, RNU6-185P, LINC00052, AC103871.1, NTRK3, MED28P6, NTRK3-AS1, MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20.
- chr15:91,853,708–98,293,199, 115 genes, copy number 9–12 (within-gene range 8–12) (broad region; genes not listed).
- chr15:98,648,539–98,964,530, 1 gene, copy number 12 (within-gene range 8–12): IGF1R.
- chr15:98,784,426–99,916,818, 29 genes, copy number 9–12: MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4, DNM1P46, AC090825.2, RN7SL484P, AC090825.1.
- chr15:100,547,765–100,919,391, 19 genes, copy number 9–12: AC027020.2, RNU6-322P, PRKXP1, AC027020.1, LINS1, RNU6-181P, ASB7, Y_RNA, AC090695.1, AC087762.1, AC087762.2, AC015712.3, AC015712.1, AC015712.6, AC015712.4, AC015712.5, ALDH1A3, AC015712.7, AC015712.2.

Autosomal genes at a single copy (total copy number 1): 224. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
